Somatic mutation profile of tumor specimen 0DE7FQ from CCDI case PBBPJK, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Neoplasm, uncertain whether benign or malignant; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 13.6 years (4,956 days).
Specimen 0DE7FQ: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 25ff8ce2-7842-459f-8b48-cdbc398c69db.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DE7E2 (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/b47f1563-cbbf-49b0-9f9e-b9e302eb48f6

The open-access MAF lists 27 somatic variants for this specimen: 19 protein-altering or splice-affecting, 6 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 16, Silent 6, Nonsense Mutation 2, Splice Region 1, RNA 1, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- H3-3A | c.83A>T p.K28M | Missense Mutation (SNP) | VAF 72/315 reads (23%) | hotspot (GDC flag); SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.697); catalogued as rs1057519903, COSV64731746, COSV64731769; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.721T>A p.S241T | Missense Mutation (SNP) | VAF 128/370 reads (35%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as CD984149, CM942121, COSV52670786, COSV52675302, COSV53004514; called by muse, mutect2, varscan2
- ADGRE3 | c.1420G>A p.V474I | Missense Mutation (SNP) | VAF 88/389 reads (23%) | SIFT tolerated (0.25); PolyPhen benign (0.179); catalogued as rs559170756, COSV53729032; called by muse, mutect2, varscan2
- ALG11 | c.340G>A p.E114K | Missense Mutation (SNP) | VAF 138/457 reads (30%) | SIFT tolerated (0.41); PolyPhen benign (0.012); catalogued as COSV101584396; called by muse, mutect2, varscan2
- ATRX | c.2341C>T p.R781* | Nonsense Mutation (SNP) | VAF 111/147 reads (76%) | catalogued as COSV64873866; called by muse, mutect2, varscan2
- LPXN | c.325G>A p.V109M | Missense Mutation (SNP) | VAF 122/310 reads (39%) | SIFT tolerated (0.1); PolyPhen benign (0.027); catalogued as COSV101222910; called by muse, mutect2, varscan2
- MUC12 | c.3460G>A p.A1154T (on ENST00000379442; = p.A1011T on NM_001164462.1) | Missense Mutation (SNP) | VAF 158/225 reads (70%) | SIFT tolerated (1); PolyPhen possibly damaging (0.494); catalogued as rs1207522645; called by muse, mutect2, varscan2
- MUC5AC | c.6119G>A p.R2040H | Missense Mutation (SNP) | VAF 198/567 reads (35%) | SIFT deleterious (0); catalogued as rs1481437467; called by muse, mutect2, varscan2
- OR4Q3 | c.430G>T p.V144F | Missense Mutation (SNP) | VAF 43/103 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.887); catalogued as COSV59178107; called by muse, mutect2
- PEX11G | c.709G>A p.E237K | Missense Mutation (SNP) | VAF 93/409 reads (23%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0.007); catalogued as rs1051693459; called by muse, mutect2, varscan2
- PTPRD | c.2309T>C p.L770P | Missense Mutation (SNP) | VAF 48/172 reads (28%) | SIFT deleterious (0.02); PolyPhen benign (0.02); catalogued as rs777808586; called by muse, mutect2, varscan2
- SORCS1 | c.1484A>G p.Y495C | Missense Mutation (SNP) | VAF 106/168 reads (63%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs150053424; called by muse, mutect2, varscan2
- CDH11 | c.674A>G p.D225G | Missense Mutation (SNP) | VAF 32/414 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2
- CDH3 | c.1742C>T p.A581V | Missense Mutation (SNP) | VAF 164/449 reads (37%) | SIFT tolerated (0.94); PolyPhen benign (0.033); called by muse, mutect2, varscan2
- CLIP2 | c.1017G>A p.L339= | Splice Region (SNP) | VAF 78/374 reads (21%) | called by muse, mutect2, varscan2
- CNTNAP1 | c.1756G>T p.E586* | Nonsense Mutation (SNP) | VAF 239/622 reads (38%) | called by muse, mutect2, varscan2
- DEFB119 | c.247C>G p.L83V | Missense Mutation (SNP) | VAF 68/223 reads (30%) | SIFT tolerated, low confidence (0.26); PolyPhen benign (0); called by muse, mutect2, varscan2
- FAM166B | c.372T>G p.H124Q | Missense Mutation (SNP) | VAF 15/574 reads (3%) | SIFT tolerated (0.48); PolyPhen benign (0); called by muse, mutect2
- PCED1B | c.401A>C p.N134T | Missense Mutation (SNP) | VAF 43/274 reads (16%) | SIFT tolerated (0.3); PolyPhen benign (0.215); called by muse, mutect2, varscan2
- ARHGEF33 | c.2196C>T p.S732= | Silent (SNP) | VAF 44/196 reads (22%) | catalogued as rs1234750522; called by muse, mutect2, varscan2
- CMIP | c.960C>T p.H320= (on ENST00000537098 / NM_198390.2; = p.H226= on NM_030629.3) | Silent (SNP) | VAF 88/282 reads (31%) | catalogued as rs755861272; called by muse, mutect2, varscan2
- GRAMD1C | c.492A>G p.R164= | Silent (SNP) | VAF 42/172 reads (24%) | called by muse, mutect2, varscan2
- ODF2 | c.750A>C p.T250= (on ENST00000434106 / NM_153433.2; = p.T226= on NM_002540.5 and 4 other RefSeq transcripts) | Silent (SNP) | VAF 38/698 reads (5%) | called by muse, mutect2
- SEPTIN4 | c.1302C>T p.T434= | Silent (SNP) | VAF 76/221 reads (34%) | catalogued as rs749485958; called by muse, mutect2, varscan2
- WDR6 | c.6C>T p.D2= | Silent (SNP) | VAF 14/354 reads (4%) | called by muse, mutect2
- ASMTL | c.-22C>A | 5'UTR (SNP) | VAF 55/100 reads (55%) | called by muse, mutect2, varscan2
- GOLGA6L3 | n.696G>T | RNA (SNP) | VAF 19/62 reads (31%) | catalogued as rs1440142880; called by muse, varscan2
